Somatic mutation profile of cancer-model specimen HCM-CSHL-0727-C18-85M (3D Organoid, passage 5; aliquot HCM-CSHL-0727-C18-85M-01D-A82I-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0727-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 63.1 years (23,063 days).
Specimen HCM-CSHL-0727-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e20154cf-a6ed-4982-a9e9-08079d78a24c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0727-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0727-C18-10A-01D-A82I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a50b9460-7145-48d8-8b0a-097ddc5f6c93

The open-access MAF lists 145 somatic variants for this specimen: 102 protein-altering or splice-affecting, 34 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 34, Intron 5, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 2, RNA 2, Splice Site 2, In Frame Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 299/459 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC099489.1 | c.8381C>T p.P2794L | Missense Mutation (SNP) | VAF 159/450 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs969670824; called by muse, mutect2, varscan2
- AGTRAP | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 190/370 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs766982120, COSV58668950; called by muse, mutect2, varscan2
- APC | c.3880del p.Q1294Rfs*11 | Frame Shift Del (DEL) | VAF 180/250 reads (72%) | catalogued as CD058148, CD132712, CM930027, COSV57323524; called by mutect2, pindel, varscan2
- ARHGAP22 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 367/587 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs755640836; called by muse, mutect2, varscan2
- ATG13 | c.1163C>T p.T388M (on ENST00000359513 / NM_001346321.1; = p.T351M on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 211/247 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs756330086, COSV56318172; called by muse, mutect2, varscan2
- ATP6AP2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 231/373 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs761302416, COSV65797564; called by muse, mutect2, varscan2
- C4orf54 | c.638T>G p.L213R | Missense Mutation (SNP) | VAF 133/245 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as COSV101552088, COSV72766807, COSV72767127; called by muse, mutect2, varscan2
- CDKN2D | c.32G>C p.R11P | Missense Mutation (SNP) | VAF 495/1073 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs764428574; called by muse, mutect2, varscan2
- CEP126 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 15/136 reads (11%) | catalogued as rs757264461, COSV54822167; called by muse, mutect2, varscan2
- CNTNAP5 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 132/436 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs752392550, COSV101443557; called by muse, mutect2, varscan2
- COL19A1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 108/288 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416918271, COSV59588444; called by muse, mutect2, varscan2
- COL4A1 | c.2084C>A p.P695H | Missense Mutation (SNP) | VAF 133/716 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1429816947, COSV65432722; called by muse, mutect2, varscan2
- DLC1 | c.2995C>T p.R999* (on ENST00000276297 / NM_001348081.2; = p.R562* on NM_006094.5) | Nonsense Mutation (SNP) | VAF 87/269 reads (32%) | catalogued as rs774092695; called by muse, mutect2, varscan2
- DTX3 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 183/596 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54085346; called by muse, mutect2, varscan2
- EBF3 | c.1024C>T p.R342C (on ENST00000355311 / NM_001375392.1; = p.R333C on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 192/346 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1265541353; called by muse, mutect2, varscan2
- GRB10 | c.1343C>T p.P448L (on ENST00000398812; = p.P402L on NM_001001549.3) | Missense Mutation (SNP) | VAF 98/531 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs373960643; called by muse, mutect2, varscan2
- HRNR | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 120/545 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs140507602; called by muse, mutect2, varscan2
- IGSF1 | c.3503G>T p.W1168L | Missense Mutation (SNP) | VAF 145/473 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.174); catalogued as CM1211167; called by muse, mutect2, varscan2
- IL11RA | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 437/685 reads (64%) | catalogued as rs778089627; called by muse, mutect2, varscan2
- JADE1 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 88/196 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); catalogued as rs1209924861; called by muse, mutect2, varscan2
- KCNC2 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 230/478 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54377340; called by muse, mutect2, varscan2
- KCNQ4 | c.806_808del p.S269del | In Frame Del (DEL) | VAF 110/232 reads (47%) | catalogued as rs797044966; called by pindel, varscan2
- NAALAD2 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456705389, COSV58961846; called by muse, mutect2, varscan2
- NCF1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 51/411 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1375017077; called by muse, mutect2, varscan2
- NIBAN1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 108/353 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.938); catalogued as rs562448693, COSV62284129; called by muse, mutect2, varscan2
- NPIPB15 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 204/570 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as rs369741448, COSV70436870; called by muse, mutect2, varscan2
- NRCAM | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 105/458 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61045797; called by muse, mutect2, varscan2
- NSUN4 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 140/272 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.554); catalogued as rs761997164; called by muse, mutect2, varscan2
- NXF1 | c.1464C>A p.S488R | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV53677345; called by muse, mutect2
- OR5L1 | c.32A>C p.E11A | Missense Mutation (SNP) | VAF 113/343 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100449910, COSV61732894; called by muse, mutect2, varscan2
- PANX3 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 125/341 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52511495; called by muse, mutect2, varscan2
- PDZD4 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 130/488 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782685044, COSV51251573; called by muse, mutect2, varscan2
- PHLPP1 | c.1601C>G p.S534C | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as rs373755664; called by muse, mutect2, varscan2
- PKD1 | c.3595G>A p.G1199S | Missense Mutation (SNP) | VAF 433/683 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs550230113; called by muse, mutect2, varscan2
- RIMS2 | c.2117G>A p.R706H (on ENST00000666250 / NM_001348490.2; = p.R514H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/160 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs754256738, COSV51679147, COSV99154333; called by muse, mutect2, varscan2
- RYR1 | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 228/1001 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as rs780121053; called by muse, mutect2, varscan2
- SETD5 | c.3313A>G p.N1105D | Missense Mutation (SNP) | VAF 249/457 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs760024950; called by muse, mutect2, varscan2
- SGSM1 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 150/315 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768586256, COSV68509802; called by muse, mutect2, varscan2
- SIRPA | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 188/1026 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs555638361, COSV61538807; called by muse, mutect2, varscan2
- SMPD2 | c.857dup p.Q287Tfs*42 | Frame Shift Ins (INS) | VAF 239/564 reads (42%) | catalogued as rs763758360; called by mutect2, pindel, varscan2
- SNAP91 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 423/687 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs376878292, COSV52123521; called by muse, mutect2, varscan2
- SPTA1 | c.6236G>A p.R2079Q | Missense Mutation (SNP) | VAF 128/623 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs754206036, COSV63751335, COSV63757919; called by muse, varscan2
- SURF2 | c.337+1del p.X113_splice | Splice Site (DEL) | VAF 107/407 reads (26%) | catalogued as rs1564353010; called by mutect2, pindel, varscan2
- TBC1D10C | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 213/487 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs755592883, COSV56702853; called by muse, mutect2, varscan2
- TCF7L2 | c.1443-1G>C p.X481_splice (on ENST00000355995 / NM_001367943.1; = p.X458_splice on NM_030756.5) | Splice Site (SNP) | VAF 98/278 reads (35%) | catalogued as COSV53339516; called by mutect2, varscan2
- TECPR1 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 153/614 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as rs920644674; called by muse, mutect2, varscan2
- TSPYL4 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 149/608 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs371934936; called by muse, mutect2, varscan2
- TUBB4A | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 151/646 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.051); catalogued as rs373302095; called by muse, mutect2, varscan2
- USP34 | c.6301G>C p.E2101Q | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV68401128; called by muse, mutect2, varscan2
- VEGFC | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 262/262 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs554908874, COSV54594769; called by muse, mutect2, varscan2
- ZC3H3 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 178/603 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs774760836, COSV99368043; called by muse, mutect2, varscan2
- ABCA12 | c.1663T>G p.L555V (on ENST00000272895 / NM_173076.3; = p.L237V on NM_015657.3) | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ACP7 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 223/478 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AFF3 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ALDH2 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 193/541 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASPN | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CDH11 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 405/623 reads (65%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP221 | c.535T>G p.Y179D | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- CHML | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CMKLR1 | c.952T>G p.F318V (on ENST00000312143 / NM_001142344.2; = p.F316V on NM_004072.3) | Missense Mutation (SNP) | VAF 138/438 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- COPE | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 130/551 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- CYLC1 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DLD | c.98G>C p.R33T | Missense Mutation (SNP) | VAF 74/447 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK11 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBLN1 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 227/378 reads (60%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); called by muse, mutect2
- EGR4 | c.1033G>A p.D345N (on ENST00000545030; = p.D242N on NM_001965.4) | Missense Mutation (SNP) | VAF 145/512 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- EPHA2 | c.1729T>C p.S577P | Missense Mutation (SNP) | VAF 200/396 reads (51%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FYCO1 | c.950C>A p.T317K | Missense Mutation (SNP) | VAF 162/462 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GATA4 | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 314/882 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR37L1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 768/1039 reads (74%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- GPRASP1 | c.3496A>G p.I1166V | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- HDAC9 | c.2810C>A p.T937K | Missense Mutation (SNP) | VAF 168/372 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- HIPK1 | c.1856del p.S619Yfs*35 | Frame Shift Del (DEL) | VAF 145/362 reads (40%) | called by mutect2, pindel, varscan2
- IRX5 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 100/296 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP11 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 293/1014 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MALRD1 | c.6112G>C p.V2038L | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- MECOM | c.626T>C p.M209T (on ENST00000468789 / NM_001105078.4; = p.M397T on NM_004991.4) | Missense Mutation (SNP) | VAF 126/468 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MNDA | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 114/492 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- MTMR12 | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 68/339 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MYO5A | c.4553G>A p.R1518Q | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NID2 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 225/225 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- OR2J1 | c.191T>G p.L64R | Missense Mutation (SNP) | VAF 104/183 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4C5 | c.278G>T p.C93F | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR9H1P | c.547T>G p.L183V | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- PARP11 | c.574dup p.R192Kfs*7 | Frame Shift Ins (INS) | VAF 128/224 reads (57%) | called by mutect2, varscan2
- PGK2 | c.548A>G p.H183R | Missense Mutation (SNP) | VAF 182/434 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTH2R | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 92/316 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RAPGEF6 | c.2962G>T p.D988Y | Missense Mutation (SNP) | VAF 140/276 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBP3 | c.2846C>A p.A949D | Missense Mutation (SNP) | VAF 200/630 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RELN | c.9184T>A p.F3062I | Missense Mutation (SNP) | VAF 94/343 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- REM1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 158/926 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RNF43 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 147/690 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SLC13A3 | c.1103C>A p.A368D | Missense Mutation (SNP) | VAF 62/531 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- SLC8A3 | c.718T>G p.F240V | Missense Mutation (SNP) | VAF 141/266 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SYT12 | c.230G>C p.R77T | Missense Mutation (SNP) | VAF 219/259 reads (85%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM101 | c.85T>G p.W29G | Missense Mutation (SNP) | VAF 161/526 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TTN | c.35867T>G p.V11956G (on ENST00000591111; = p.V4532G on NM_003319.4) | Missense Mutation (SNP) | VAF 81/309 reads (26%) | PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- UBE3B | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP9X | c.4249A>G p.T1417A | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZFC3H1 | c.1454A>T p.Y485F | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF302 | c.1382C>G p.S461* (on ENST00000627982; = p.S382* on NM_018443.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/121 reads (16%) | called by muse, mutect2, varscan2
- APOL1 | c.891G>A p.P297= | Silent (SNP) | VAF 226/226 reads (100%) | catalogued as rs148496792; called by muse, varscan2
- ARL8A | c.480C>T p.Y160= | Silent (SNP) | VAF 95/491 reads (19%) | catalogued as rs922264836, COSV55343536; called by muse, mutect2, varscan2
- C20orf194 | c.783G>A p.A261= | Silent (SNP) | VAF 102/397 reads (26%) | catalogued as rs372936526; called by muse, mutect2, varscan2
- C2CD5 | c.1170A>G p.A390= | Silent (SNP) | VAF 98/182 reads (54%) | called by muse, mutect2, varscan2
- CCDC81 | c.1921C>T p.L641= (on ENST00000445632 / NM_001156474.2; = p.L551= on NM_021827.4) | Silent (SNP) | VAF 289/351 reads (82%) | called by muse, mutect2, varscan2
- CGB2 | c.30G>A p.L10= | Silent (SNP) | VAF 60/762 reads (8%) | called by muse, mutect2
- CNTNAP4 | c.1680C>T p.H560= | Silent (SNP) | VAF 180/293 reads (61%) | catalogued as rs779366718; called by muse, mutect2, varscan2
- CPNE5 | c.648C>T p.H216= | Silent (SNP) | VAF 42/398 reads (11%) | catalogued as COSV55200942; called by muse, mutect2, varscan2
- CTC1 | c.2055G>A p.Q685= | Silent (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- EPN1 | c.471C>T p.T157= | Silent (SNP) | VAF 266/578 reads (46%) | catalogued as rs769366217, COSV99321742; called by muse, mutect2, varscan2
- EPS15 | c.477G>A p.K159= | Silent (SNP) | VAF 48/286 reads (17%) | called by muse, mutect2, varscan2
- GASK1B | c.456G>T p.P152= | Silent (SNP) | VAF 422/604 reads (70%) | catalogued as COSV56707032; called by muse, mutect2, varscan2
- ITPRID2 | c.1437T>C p.A479= | Silent (SNP) | VAF 73/276 reads (26%) | catalogued as rs986947252; called by muse, mutect2, varscan2
- LCP2 | c.237G>A p.R79= | Silent (SNP) | VAF 115/391 reads (29%) | called by muse, mutect2, varscan2
- LRRC38 | c.237C>T p.Y79= | Silent (SNP) | VAF 249/479 reads (52%) | catalogued as rs758192768, COSV101065864; called by muse, mutect2, varscan2
- MOB3A | c.360C>T p.D120= | Silent (SNP) | VAF 328/684 reads (48%) | called by muse, mutect2
- MTUS2 | c.1749G>A p.T583= | Silent (SNP) | VAF 112/734 reads (15%) | catalogued as rs757126872, COSV70917100; called by muse, mutect2, varscan2
- MYO1C | c.2979G>T p.V993= (on ENST00000648651 / NM_001080779.2; = p.V958= on NM_033375.5) | Silent (SNP) | VAF 320/320 reads (100%) | called by muse, mutect2, varscan2
- NCOA3 | c.1236G>A p.P412= | Silent (SNP) | VAF 189/1072 reads (18%) | catalogued as rs764068924; called by muse, mutect2, varscan2
- OR4A15 | c.495T>A p.P165= | Silent (SNP) | VAF 49/268 reads (18%) | catalogued as COSV100124152; called by muse, mutect2, varscan2
- PANK4 | c.2169C>T p.I723= | Silent (SNP) | VAF 288/566 reads (51%) | catalogued as rs1234065580, COSV53943592; called by muse, mutect2, varscan2
- PHOX2B | c.645C>T p.G215= | Silent (SNP) | VAF 206/392 reads (53%) | catalogued as COSV56928465; called by mutect2, varscan2
- PIK3CG | c.1116C>T p.V372= | Silent (SNP) | VAF 170/663 reads (26%) | called by muse, mutect2, varscan2
- PRLHR | c.390C>T p.G130= | Silent (SNP) | VAF 269/808 reads (33%) | catalogued as COSV53303647; called by muse, mutect2, varscan2
- PXDN | c.1203C>T p.N401= | Silent (SNP) | VAF 155/461 reads (34%) | catalogued as rs1381055153, COSV53238596; ClinVar: likely benign; called by muse, mutect2, varscan2
- RXRG | c.333C>T p.D111= | Silent (SNP) | VAF 397/542 reads (73%) | called by muse, mutect2, varscan2
- SF3B2 | c.193C>T p.L65= | Silent (SNP) | VAF 112/332 reads (34%) | called by muse, mutect2, varscan2
- SFXN4 | c.396G>A p.K132= | Silent (SNP) | VAF 78/289 reads (27%) | catalogued as COSV100340987; called by muse, mutect2, varscan2
- SYT3 | c.1014C>T p.Y338= | Silent (SNP) | VAF 173/618 reads (28%) | catalogued as rs904387799, COSV104409420; called by muse, mutect2, varscan2
- TDG | c.840T>A p.P280= | Silent (SNP) | VAF 40/265 reads (15%) | called by muse, mutect2, varscan2
- TGIF2 | c.654G>A p.Q218= | Silent (SNP) | VAF 311/717 reads (43%) | called by muse, mutect2, varscan2
- THEMIS | c.1146C>T p.S382= | Silent (SNP) | VAF 294/689 reads (43%) | catalogued as rs1180503642, COSV64072401, COSV64072792; called by muse, mutect2, varscan2
- USP42 | c.1602G>A p.Q534= | Silent (SNP) | VAF 175/411 reads (43%) | called by muse, mutect2, varscan2
- WFIKKN1 | c.816G>A p.L272= | Silent (SNP) | VAF 450/686 reads (66%) | called by muse, varscan2
- ABCD1 | c.-199G>T | 5'UTR (SNP) | VAF 175/554 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.657+130G>A | Intron (SNP) | VAF 147/445 reads (33%) | catalogued as rs767265337; called by muse, mutect2, varscan2
- BEAN1 | c.*262G>A | 3'UTR (SNP) | VAF 168/499 reads (34%) | called by muse, mutect2, varscan2
- DHX30 | c.125-2289C>G | Intron (SNP) | VAF 183/603 reads (30%) | catalogued as rs1174589727; called by muse, mutect2, varscan2
- FARP1 | c.1414+544C>A | Intron (SNP) | VAF 123/609 reads (20%) | called by muse, mutect2, varscan2
- LINC01619 | n.1504G>A | RNA (SNP) | VAF 64/144 reads (44%) | called by muse, mutect2, varscan2
- LSP1 | c.53+13339C>A | Intron (SNP) | VAF 375/439 reads (85%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2641G>A | RNA (SNP) | VAF 169/829 reads (20%) | catalogued as rs747017426; called by muse, mutect2, varscan2
- TTN | c.34264+5293G>A | Intron (SNP) | VAF 77/261 reads (30%) | catalogued as rs1209026573, COSV60114890, COSV60160537; ClinVar: likely benign; called by muse, mutect2, varscan2
